Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4SW, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4SW-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

Left upper lobe lung (195 grams), superior mediastinal (tracheobronchial), inferior mediastinal (subcarinal, paraesophageal) and N1 (interlobar) lymph nodes. A1, A2, A3, A4, A5, A6, B1, B2, B3, B4, B5, B6, B7, B8, B9

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Grade 3 (of 4) adenocarcinoma forming a 3.5 x 3.2 x 3 cm subpleural mass located 2 cm from the bronchial margin. The tumor puckers but does not involve the overlying pleura. The surgical margins are negative for tumor. Multiple 2 (of 10) intrapulmonary peribronchial lymph nodes are positive for metastatic adenocarcinoma without extranodal extension.

Lymph nodes, superior and inferior mediastinal, N1, excision: Multiple (1 tracheobronchial, 1 subcarinal, 1 paraesophageal, 4 interlobar) lymph nodes are negative for tumor.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Lung, upper lobe C34.1

hw
10/27/12

Source: NCI Genomic Data Commons file f9da8591-02a2-4025-b1fb-2a86aafbf63e (TCGA-MP-A4SW.2A3C5E05-A4B8-4C01-B61D-3C46E9614707.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).